Somatic mutation profile of tumor specimen TCGA-AZ-4614-01A (aliquot TCGA-AZ-4614-01A-01D-1408-10) from TCGA case TCGA-AZ-4614, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVA; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-AZ-4614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33fdcf1e-8739-4289-a2de-307d51a0acc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4614-10A (Blood Derived Normal), aliquot TCGA-AZ-4614-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3191bb00-7773-4dc7-800d-20816ee59795

The open-access MAF lists 200 somatic variants for this specimen: 145 protein-altering or splice-affecting, 48 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 48, Nonsense Mutation 6, Frame Shift Del 4, Intron 4, Splice Site 3, Frame Shift Ins 3, RNA 2, Splice Region 2, In Frame Del 2, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SMAD4 | c.153dup p.D52Rfs*2 | Frame Shift Ins (INS) | VAF 40/70 reads (57%) | catalogued as rs786203560; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 49/66 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.762A>C p.G254= | Splice Region (SNP) | VAF 50/56 reads (89%) | catalogued as COSV101257066; called by muse, mutect2, varscan2
- ADAM12 | c.1295T>G p.V432G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64107719; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1072+1G>T p.X358_splice | Splice Site (SNP) | VAF 50/114 reads (44%) | catalogued as COSV54435883, COSV99717531; called by muse, mutect2, varscan2
- ADGRL2 | c.1029T>G p.I343M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs552007701, COSV54670069; called by muse, mutect2, varscan2
- ADGRV1 | c.16861T>G p.S5621A | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101315613; called by muse, mutect2, varscan2
- ADH1A | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs764209859, COSV52924575; called by muse, mutect2, varscan2
- AFF2 | c.2586G>C p.E862D | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV53991980; called by muse, mutect2
- AIFM3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.826); catalogued as COSV100104346; called by muse, mutect2, varscan2
- AKAP12 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759658755, COSV53571351; called by muse, mutect2, varscan2
- ALK | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as rs187200776, COSV66562776, COSV66585781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP30 | c.3142A>G p.S1048G (on ENST00000368013 / NM_001025598.2; = p.S837G on NM_181720.3) | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100920160; called by muse, mutect2, varscan2
- ASPM | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV99659803; called by muse, mutect2, varscan2
- ATP10A | c.3517T>A p.F1173I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100790990; called by muse, varscan2
- ATP6V1B2 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99369327; called by muse, mutect2, varscan2
- BRINP1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148052034, COSV56309641; called by muse, mutect2, varscan2
- C17orf97 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as COSV64076644; called by muse, mutect2, varscan2
- C19orf44 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as COSV99684974; called by muse, mutect2, varscan2
- C8A | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867579307, COSV63483440; called by muse, mutect2, varscan2
- CACNA1H | c.6965G>A p.R2322Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1468102052, COSV52352905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCSER2 | c.1238A>G p.D413G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1282004190, COSV99825616; called by muse, mutect2, varscan2
- CHD4 | c.2274+1G>T p.X758_splice (on ENST00000357008 / NM_001363606.2; = p.X771_splice on NM_001273.5) | Splice Site (SNP) | VAF 7/147 reads (5%) | catalogued as COSV58902315; called by muse, mutect2
- CHRDL1 | c.203T>C p.L68P (on ENST00000372045; = p.L74P on NM_145234.4) | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.478); catalogued as COSV99487821; called by muse, mutect2
- CKAP5 | c.3916C>T p.R1306C | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100370543; called by muse, mutect2, varscan2
- CLVS2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV51564820; called by muse, mutect2, varscan2
- CMTR2 | c.1994_1996del p.C665del | In Frame Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs755655082; called by pindel, varscan2
- CNOT1 | c.4252A>G p.T1418A | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as COSV55317588; called by muse, mutect2, varscan2
- CNR1 | c.1307C>A p.A436E | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100759178; called by muse, mutect2, varscan2
- COL1A2 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 211/525 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99798904; called by muse, mutect2, varscan2
- COL3A1 | c.4282G>A p.V1428I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100482673; called by muse, mutect2, varscan2
- COQ2 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV61021691; called by muse, mutect2, varscan2
- CPEB1 | c.1075C>A p.L359I (on ENST00000617958; = p.L299I on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99917531; called by muse, mutect2, varscan2
- DHX33 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 75/92 reads (82%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs745955062, COSV56579225; called by muse, mutect2, varscan2
- DLG2 | c.1986A>C p.Q662H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99713354; called by muse, mutect2, varscan2
- DMD | c.121T>G p.F41V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55875573; called by muse, mutect2, varscan2
- DMRT2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140044845; called by muse, mutect2
- DMXL1 | c.5798G>T p.G1933V | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs754689697, COSV100223520; called by muse, mutect2, varscan2
- DPYSL5 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs41288787, COSV56512286; called by muse, mutect2, varscan2
- EDARADD | c.586C>T p.R196C (on ENST00000334232 / NM_145861.4; = p.R186C on NM_080738.4) | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs763414523, COSV62062920; called by muse, mutect2
- EIF4G1 | c.2629C>T p.R877* (on ENST00000346169 / NM_198241.3; = p.R682* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs867124532, COSV100071582; called by muse, varscan2
- EML3 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV53882783; called by muse, mutect2, varscan2
- EOMES | c.1027A>T p.N343Y | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99841788; called by muse, mutect2, varscan2
- EPHB6 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 133/320 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs751057326, COSV67418478; called by muse, varscan2
- FAAH2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 194/351 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200667637, COSV100887191; called by muse, mutect2, varscan2
- FAT4 | c.9005C>T p.T3002M | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1435573726, COSV100627638; called by muse, mutect2, varscan2
- FBN3 | c.4468G>T p.G1490W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54466649, COSV99559663; called by muse, mutect2, varscan2
- FBXL5 | c.1124+1G>C p.X375_splice | Splice Site (SNP) | VAF 104/201 reads (52%) | catalogued as COSV58011265, COSV58011691; called by muse, mutect2, varscan2
- FGFRL1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394687918, COSV99294511; called by muse, varscan2
- FH | c.601A>T p.I201L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100844988; called by muse, mutect2, varscan2
- FHOD3 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758818742, COSV99940480; called by muse, mutect2
- GDF6 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs778407122, COSV54625147, COSV54625475, COSV99748079; called by muse, mutect2
- GOLGA1 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 195/532 reads (37%) | catalogued as COSV100764441, COSV100764446; called by muse, mutect2, varscan2
- HCN1 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV100299166, COSV57531281; called by muse, varscan2
- HECW1 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs368182508, COSV101222987; called by muse, mutect2, varscan2
- HIVEP2 | c.6575G>A p.G2192D | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.928); catalogued as COSV50006963; called by muse, mutect2, varscan2
- HMCN1 | c.7742A>G p.N2581S | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99625692; called by muse, mutect2, varscan2
- HYAL4 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs775190818, COSV99772102; called by muse, mutect2, varscan2
- IGF1R | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs769418210, COSV51289356; called by muse, mutect2, varscan2
- IL17A | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.845); catalogued as rs745674559, COSV100391539, COSV60684255; called by muse, varscan2
- IL20RA | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100359854; called by muse, mutect2
- ITGA10 | c.2734A>G p.T912A | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100994766; called by muse, mutect2, varscan2
- IVL | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as COSV64216226; called by muse, mutect2
- KIAA1109 | c.11096C>A p.P3699H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99148276; called by muse, mutect2
- LCP1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV100549764; called by muse, mutect2, varscan2
- LHX2 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV101010033, COSV101010079; called by muse, mutect2
- LIPI | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100753510, COSV60710202; called by muse, mutect2, varscan2
- LRRC1 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100906258; called by muse, mutect2, varscan2
- LYPLA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV57605307; called by muse, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MCOLN1 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as rs367818287; called by muse, varscan2
- MLH1 | c.615G>T p.R205S | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99212356; called by muse, mutect2, varscan2
- MLNR | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99519722; called by muse, mutect2, varscan2
- MYH14 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs767742973, COSV51837000; called by muse, mutect2
- MYO16 | c.1701G>T p.Q567H | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99193673; called by muse, mutect2, varscan2
- NAPRT | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 133/450 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99434491; called by muse, mutect2, varscan2
- NAPSA | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); catalogued as rs958024903, COSV53797179; called by muse, mutect2, varscan2
- NCKAP5 | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100490639; called by muse, mutect2, varscan2
- NDUFB11 | c.442C>T p.Q148* (on ENST00000377811 / NM_001135998.3; = p.Q158* on NM_019056.6) | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as COSV52102285; called by muse, mutect2, varscan2
- NEK11 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs142330323; called by muse, mutect2, varscan2
- NPAP1 | c.1764T>G p.I588M | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100274939; called by muse, mutect2, varscan2
- NRK | c.3799G>T p.G1267C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99686942; called by muse, mutect2, varscan2
- NRXN1 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV58457819; called by muse, mutect2, varscan2
- NTRK2 | c.1909G>A p.V637M (on ENST00000323115 / NM_001369534.1; = p.V653M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); catalogued as rs200114699, COSV99453027; called by muse, mutect2
- OR2M2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs149761766; called by muse, mutect2, varscan2
- OR4C6 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs200014503, COSV100051758, COSV58603674, COSV58606703; called by muse, mutect2
- OR52K2 | c.751T>G p.L251V | Missense Mutation (SNP) | VAF 127/348 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57835411; called by muse, mutect2, varscan2
- OR7A5 | c.667T>A p.S223T | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100457667, COSV100457739; called by muse, mutect2, varscan2
- OXSR1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs777107244, COSV61260665; called by muse, mutect2, varscan2
- PAPPA2 | c.5150G>A p.R1717Q | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs757901776, COSV100867691, COSV62789840; called by muse, mutect2, varscan2
- PCDH17 | c.1857G>C p.E619D | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV100931490, COSV100931798; called by muse, mutect2, varscan2
- PCDH19 | c.918C>A p.Y306* | Nonsense Mutation (SNP) | VAF 93/259 reads (36%) | catalogued as CM162898, COSV55259697; called by muse, mutect2, varscan2
- PCDHB10 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 197/293 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99503894; called by muse, mutect2, varscan2
- PCDHB3 | c.1395C>A p.S465R | Missense Mutation (SNP) | VAF 84/124 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV99164378; called by muse, mutect2, varscan2
- PRUNE2 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546948015, COSV100944300; called by muse, mutect2
- PZP | c.1933T>A p.F645I | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99736836; called by muse, mutect2, varscan2
- RABEPK | c.896G>A p.C299Y | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1417602322, COSV99413302; called by muse, mutect2, varscan2
- RBFOX2 | c.701C>T p.A234V (on ENST00000438146 / NM_001349995.2; = p.A164V on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99455184; called by muse, mutect2, varscan2
- RBM26 | c.2593G>A p.G865S (on ENST00000438737 / NM_001366735.2; = p.G838S on NM_022118.5) | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV99935911; called by muse, mutect2, varscan2
- RIMS1 | c.4370C>T p.S1457L | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs770684710, COSV99324962; called by muse, mutect2, varscan2
- RMI1 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100366102; called by muse, mutect2, varscan2
- SCGN | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as rs756848200, COSV58545082; called by muse, mutect2, varscan2
- SCN1A | c.5581C>T p.R1861W (on ENST00000303395 / NM_001202435.3; = p.R1850W on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1211397, COSV100319670; called by muse, mutect2, varscan2
- SEC61A1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99684750; called by muse, mutect2, varscan2
- SELE | c.1758G>T p.K586N | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100324557; called by muse, mutect2, varscan2
- SEMA6D | c.2339T>G p.L780R (on ENST00000316364 / NM_153618.2; = p.L718R on NM_020858.2) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100316601; called by muse, mutect2, varscan2
- SERPINA9 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 124/252 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100098028, COSV54077518; called by muse, mutect2, varscan2
- SETX | c.6281T>G p.L2094R | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809069; called by muse, mutect2, varscan2
- SIGLEC10 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs201054656; called by muse, mutect2, varscan2
- SLC16A1 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs767509828, COSV63709500; called by muse, mutect2, varscan2
- SLC44A5 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs146716753; called by muse, mutect2, varscan2
- SPART | c.1818C>G p.N606K | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100768607; called by muse, mutect2, varscan2
- SPATA17 | c.510C>A p.S170R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860950; called by muse, mutect2, varscan2
- SPATA31A3 | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 156/445 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1439407192; called by muse, mutect2, varscan2
- STKLD1 | c.1958_1961del p.S653Tfs*67 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs868276358; called by pindel, varscan2
- SUSD2 | c.406C>G p.H136D | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99572852; called by muse, mutect2, varscan2
- SVEP1 | c.7672T>A p.S2558T | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV99928556; called by muse, mutect2, varscan2
- TAAR8 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 199/414 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs750414571, COSV51586014; called by muse, mutect2, varscan2
- TACC1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs377342873; called by muse, mutect2
- TAF13 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs771211231, COSV100615478; called by muse, mutect2, varscan2
- TBC1D8B | c.706C>G p.H236D | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV99344013; called by muse, mutect2, varscan2
- TENM3 | c.6521G>A p.R2174H | Missense Mutation (SNP) | VAF 70/98 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs751169755, COSV69300050; called by muse, mutect2
- THSD7B | c.4501A>G p.I1501V (on ENST00000272643; = p.I1499V on NM_001316349.2) | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs748732768, COSV99746290; called by muse, mutect2, varscan2
- TLE4 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 71/158 reads (45%) | catalogued as COSV54633019; called by muse, mutect2, varscan2
- TP53BP1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 32/645 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99780034; called by muse, mutect2
- TRPS1 | c.7C>T p.R3W (on ENST00000220888 / NM_001330599.2; = p.R16W on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55227623; called by muse, mutect2, varscan2
- UBQLN1 | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99973223; called by muse, mutect2, varscan2
- UGGT1 | c.1728C>A p.N576K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV99390386; called by muse, mutect2, varscan2
- UGT2B11 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs200374868; called by muse, mutect2, varscan2
- VEPH1 | c.1877G>A p.S626N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.789); catalogued as COSV100747431; called by muse, mutect2, varscan2
- XIRP2 | c.4559T>G p.L1520R (on ENST00000628543; = p.L1695R on NM_152381.6) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99739933; called by muse, mutect2, varscan2
- XPOT | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 70/86 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100225397; called by muse, mutect2, varscan2
- ZBED9 | c.423C>G p.V141= | Splice Region (SNP) | VAF 27/68 reads (40%) | catalogued as COSV101509162; called by muse, mutect2, varscan2
- ZFHX4 | c.1746A>T p.E582D | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99258932; called by muse, mutect2, varscan2
- ZFHX4 | c.7550T>G p.L2517R | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99257146; called by muse, mutect2, varscan2
- ZNF117 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.2); catalogued as rs1274215259, COSV99275296; called by muse, mutect2
- ZXDA | c.1149C>G p.F383L | Missense Mutation (SNP) | VAF 160/533 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV100699377, COSV62388764; called by muse, mutect2, varscan2
- AMER1 | c.1526_1527dup p.E510Mfs*32 | Frame Shift Ins (INS) | VAF 114/190 reads (60%) | called by mutect2, pindel, varscan2
- KRI1 | c.343_346delinsG p.L115_K116delinsE | In Frame Del (DEL) | VAF 74/216 reads (34%) | called by pindel, varscan2*
- MTIF2 | c.218del p.K73Rfs*19 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by pindel, varscan2
- MUC5B | c.6214dup p.T2072Nfs*52 | Frame Shift Ins (INS) | VAF 171/584 reads (29%) | called by pindel, varscan2
- POTEA | c.1480C>A p.H494N (on ENST00000519951 / NM_001005365.2; = p.H448N on NM_001002920.1) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.553); called by muse, mutect2
- RAB6D | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 247/725 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK3 | c.5054del p.N1685Tfs*71 | Frame Shift Del (DEL) | VAF 224/1383 reads (16%) | called by mutect2, pindel, varscan2
- ABCC1 | c.2859G>A p.A953= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs372453304; called by muse, mutect2
- ANKRD16 | c.792C>T p.V264= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1397605309, COSV99510376; called by muse, mutect2
- ASCL3 | c.114C>T p.H38= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as rs144588221; called by muse, mutect2, varscan2
- CAD | c.5346C>T p.T1782= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs772273421, COSV53023666; called by muse, mutect2, varscan2
- CCDC7 | c.252C>A p.I84= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV53227331, COSV99511410; called by muse, mutect2, varscan2
- CDYL2 | c.903C>T p.S301= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as rs141862110; called by muse, mutect2
- CGGBP1 | c.252G>A p.R84= | Silent (SNP) | VAF 63/82 reads (77%) | catalogued as COSV100531819, COSV58852298; called by muse, mutect2, varscan2
- DGKB | c.378T>C p.N126= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs764522255, COSV99337304; called by muse, mutect2, varscan2
- EFCAB6 | c.339C>T p.D113= | Silent (SNP) | VAF 81/115 reads (70%) | catalogued as rs1390243497, COSV53064664; called by muse, mutect2, varscan2
- FAT4 | c.14622A>G p.Q4874= | Silent (SNP) | VAF 72/247 reads (29%) | catalogued as rs761187408, COSV58672325, COSV58674006, COSV58679733; called by muse, mutect2, varscan2
- FLRT2 | c.825G>T p.L275= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV100420128, COSV58148178; called by muse, mutect2, varscan2
- GCM2 | c.519C>T p.S173= | Silent (SNP) | VAF 120/280 reads (43%) | catalogued as rs781711581, COSV65275104, COSV65275646; called by muse, mutect2
- GSTP1 | c.549C>A p.R183= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV101282008; called by muse, mutect2
- KCNT1 | c.2307C>T p.N769= (on ENST00000488444; = p.N788= on NM_020822.3) | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as COSV99705230; called by muse, mutect2, varscan2
- MARK3 | c.258A>T p.I86= | Silent (SNP) | VAF 81/214 reads (38%) | catalogued as COSV99357968; called by muse, mutect2, varscan2
- MUC5AC | c.645C>T p.N215= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs780428239, COSV62254411; called by muse, mutect2, varscan2
- MYH9 | c.3813G>A p.L1271= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV99338147; called by muse, varscan2
- MYO16 | c.1702C>T p.L568= | Silent (SNP) | VAF 76/192 reads (40%) | catalogued as COSV99193674; called by muse, mutect2, varscan2
- NDUFB11 | c.441C>T p.I147= (on ENST00000377811 / NM_001135998.3; = p.I157= on NM_019056.6) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV52102300; called by muse, mutect2, varscan2
- NOD2 | c.858C>T p.G286= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV100318306; called by muse, mutect2, varscan2
- NPAS4 | c.360C>T p.Y120= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as rs377576767, COSV60650442; called by muse, mutect2, varscan2
- NR0B1 | c.240C>G p.L80= | Silent (SNP) | VAF 143/188 reads (76%) | catalogued as COSV66763994, COSV66764157; called by muse, varscan2
- OR14C36 | c.48T>C p.S16= | Silent (SNP) | VAF 43/389 reads (11%) | catalogued as rs1409345409, COSV100507430; called by muse, mutect2, varscan2
- OR8U1 | c.564T>G p.T188= | Silent (SNP) | VAF 206/545 reads (38%) | catalogued as COSV100164103, COSV56419275; called by muse, mutect2, varscan2
- ORM1 | c.174G>A p.S58= | Silent (SNP) | VAF 148/413 reads (36%) | catalogued as rs11552129; called by muse, mutect2, varscan2
- PAPPA | c.2817A>T p.T939= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100073216; called by muse, mutect2, varscan2
- PCDH9 | c.3153T>A p.V1051= (on ENST00000377865 / NM_203487.3; = p.V1017= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV100119129; called by muse, mutect2, varscan2
- PDE3B | c.3042A>G p.L1014= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV99962163; called by muse, mutect2, varscan2
- PLEKHG6 | c.114C>T p.L38= | Silent (SNP) | VAF 70/79 reads (89%) | catalogued as COSV99164117; called by muse, mutect2, varscan2
- PLXNA1 | c.5535G>A p.Q1845= | Silent (SNP) | VAF 105/283 reads (37%) | catalogued as COSV99302552; called by muse, mutect2, varscan2
- POLG | c.3444C>T p.R1148= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs374937961, COSV99174528; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2
- POSTN | c.2325T>C p.T775= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs898373291, COSV101123272; called by muse, mutect2, varscan2
- PRSS54 | c.615C>T p.C205= | Silent (SNP) | VAF 198/419 reads (47%) | catalogued as rs775521419, COSV54687879; called by muse, mutect2, varscan2
- QTRT1 | c.567T>C p.H189= | Silent (SNP) | VAF 56/127 reads (44%) | catalogued as COSV51551608; called by muse, mutect2, varscan2
- RNF220 | c.750G>T p.L250= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as COSV100698411; called by muse, mutect2, varscan2
- ROS1 | c.3840A>G p.V1280= | Silent (SNP) | VAF 60/102 reads (59%) | catalogued as rs1476652672, COSV100876646; called by muse, mutect2, varscan2
- SERPINE2 | c.219C>T p.T73= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as COSV99296448; called by muse, mutect2, varscan2
- SHANK2 | c.3498G>A p.P1166= | Silent (SNP) | VAF 55/117 reads (47%) | catalogued as rs1174074101, COSV99572756; called by muse, varscan2
- SIK2 | c.240C>T p.I80= | Silent (SNP) | VAF 41/52 reads (79%) | catalogued as COSV100516017; called by muse, mutect2, varscan2
- SLC35F4 | c.972T>C p.N324= (on ENST00000339762 / NM_001352015.2; = p.N288= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1206851041, COSV100333632; called by muse, mutect2, varscan2
- SPDYE5 | c.966G>A p.P322= | Silent (SNP) | VAF 135/441 reads (31%) | catalogued as rs782181392; called by muse, mutect2, varscan2
- THAP9 | c.1812T>G p.T604= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100155772; called by muse, mutect2, varscan2
- TNXB | c.1587C>T p.P529= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as rs777108458, COSV100926027; called by muse, varscan2
- TOP2B | c.288T>G p.V96= (on ENST00000264331 / NM_001330700.2; = p.V91= on NM_001068.3) | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as COSV99979383; called by muse, mutect2, varscan2
- TSNAXIP1 | c.466C>T p.L156= | Silent (SNP) | VAF 111/306 reads (36%) | catalogued as COSV99534905; called by muse, mutect2, varscan2
- TUBB4A | c.291C>T p.A97= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as rs1280567008, COSV99899908; called by muse, mutect2, varscan2
- WDR86 | c.291G>A p.T97= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs374169529; called by muse, mutect2, varscan2
- WSCD2 | c.1548C>A p.G516= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99774237; called by muse, mutect2, varscan2
- ACKR3 | c.-2C>T | 5'UTR (SNP) | VAF 73/171 reads (43%) | catalogued as rs1421300780, COSV99799384; called by muse, mutect2, varscan2
- CCDC140 | n.844G>C | RNA (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54675811; called by muse, mutect2, varscan2
- DLG2 | c.205-65662G>A | Intron (SNP) | VAF 43/98 reads (44%) | catalogued as rs775279744, COSV54644917, COSV99713356; called by muse, mutect2, varscan2
- HTR2C | c.350-24537A>G | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99348484; called by muse, varscan2
- HTR2C | c.350-24471G>T | Intron (SNP) | VAF 18/91 reads (20%) | catalogued as COSV99348486, COSV99350959; called by muse, varscan2
- POLA1 | c.2947-21098A>T | Intron (SNP) | VAF 90/136 reads (66%) | catalogued as COSV66886847; called by muse, mutect2, varscan2
- SSPOP | n.9006C>T | RNA (SNP) | VAF 31/362 reads (9%) | catalogued as rs760582657, COSV100947131; called by muse, mutect2
